Somatic mutation profile of tumor specimen C3L-02858-01 (aliquot CPT0389160006) from CPTAC case C3L-02858, project CPTAC-3 (Kidney — Lipomatous Neoplasms). Sex at birth: female; Vital status: Alive; Primary diagnosis: Angiomyolipoma; Tissue or organ of origin: Kidney, NOS; Tumor grade: GX; Age at diagnosis: 39.8 years (14,545 days).
Specimen C3L-02858-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c495b66a-3499-4145-a412-10bcc899c56b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02858-31 (Blood Derived Normal), aliquot CPT0389210002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c89e87f5-bddf-4b32-8daf-643c8e9d712c

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 3, Missense Mutation 2, Nonsense Mutation 2, Silent 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CENPF | c.9280C>T p.R3094* | Nonsense Mutation (SNP) | VAF 124/540 reads (23%) | catalogued as rs869312748, CM162211, COSV65276590; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MCMDC2 | c.332A>G p.Y111C | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58033346; called by muse, mutect2, varscan2
- TSC2 | c.4654G>T p.E1552* | Nonsense Mutation (SNP) | VAF 115/373 reads (31%) | catalogued as rs397514942, CM052385; ClinVar: not provided; called by muse, mutect2, varscan2
- TSC2 | c.2182_2215del p.C728Pfs*32 | Frame Shift Del (DEL) | VAF 81/332 reads (24%) | called by mutect2, pindel
- YY1AP1 | c.706G>C p.A236P (on ENST00000295566 / NM_139118.2; = p.A159P on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/628 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- OPTC | c.252T>G p.A84= | Silent (SNP) | VAF 79/994 reads (8%) | called by muse, mutect2
- C1D | c.-9-5817C>G | Intron (SNP) | VAF 64/286 reads (22%) | called by muse, mutect2, varscan2
- SFRP1 | c.544+1845C>T | Intron (SNP) | VAF 13/394 reads (3%) | called by muse, mutect2
- SLC12A6 | c.2633-43C>G | Intron (SNP) | VAF 38/312 reads (12%) | called by muse, mutect2, varscan2
